Somatic mutation profile of tumor specimen TCGA-04-1342-01A (aliquot TCGA-04-1342-01A-01W-0486-08) from TCGA case TCGA-04-1342, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 80.8 years (29,501 days).
Specimen TCGA-04-1342-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41e502a9-ff9d-4524-b4bd-02d0be0668a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1342-11A (Solid Tissue Normal), aliquot TCGA-04-1342-11A-01W-0487-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f510f4e6-1fd7-4bb7-90dc-28df728f23e0

The open-access MAF lists 103 somatic variants for this specimen: 69 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 30, Nonsense Mutation 5, Frame Shift Ins 4, Frame Shift Del 4, Intron 2, RNA 1, Splice Site 1, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB9 | c.2098C>T p.R700W (on ENST00000280560 / NM_019625.4; = p.R657W on NM_019624.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751711542, COSV54893333; called by muse, mutect2, varscan2
- ALKBH1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 108/358 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV53660593; called by muse, mutect2, varscan2
- ANKRD12 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50836631; called by muse, mutect2, varscan2
- BRSK1 | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 83/126 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58667791, COSV58668405; called by muse, mutect2, varscan2
- BSN | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs572736678, COSV56523448; called by muse, mutect2, varscan2
- CAMK4 | c.986C>A p.A329E | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56678041, COSV99998851; called by muse, varscan2
- CATSPERB | c.3187G>T p.A1063S | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.391); catalogued as COSV99831327; called by muse, mutect2
- CENPJ | c.1544C>A p.T515K | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1230889329, COSV67883870; called by muse, mutect2
- DLGAP3 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99332758; called by muse, mutect2
- DNAJC14 | c.501G>T p.L167F | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.946); catalogued as COSV100423613; called by muse, mutect2
- DNM2 | c.717G>T p.Q239H | Missense Mutation (SNP) | VAF 17/516 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV100117313; called by muse, mutect2
- FCAMR | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV61367047; called by muse, mutect2
- GLMP | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV55296501; called by muse, mutect2, varscan2
- GRIP2 | c.3139C>T p.R1047W (on ENST00000619221; = p.R950W on NM_001080423.4) | Missense Mutation (SNP) | VAF 88/286 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.944); catalogued as rs1489641967, COSV56123241; called by muse, mutect2, varscan2
- HAS3 | c.1130T>A p.L377H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99544420; called by mutect2, varscan2
- INTS5 | c.1385T>C p.L462P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.865); catalogued as COSV57952804; called by muse, mutect2, varscan2
- KIT | c.2870T>C p.I957T | Missense Mutation (SNP) | VAF 116/402 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV55412662; called by muse, mutect2, varscan2
- L1CAM | c.3234G>A p.W1078* | Nonsense Mutation (SNP) | VAF 197/404 reads (49%) | catalogued as COSV100648873, COSV62829305; called by muse, mutect2, varscan2
- LAMB2 | c.3790G>A p.E1264K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV59736028; called by muse, mutect2, varscan2
- LHCGR | c.1577T>C p.V526A | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.88); PolyPhen benign (0.01); catalogued as COSV99683764; called by muse, mutect2
- LILRB1 | c.1799G>A p.R600Q (on ENST00000427581; = p.R550Q on NM_006669.6) | Missense Mutation (SNP) | VAF 73/344 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs773925105, COSV100206809; called by muse, mutect2, varscan2
- MICALL1 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV53241318, COSV53242269; called by mutect2, varscan2
- MKI67 | c.1226C>A p.A409D | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.017); catalogued as COSV100896600; called by muse, mutect2
- MTRR | c.1836G>T p.R612S (on ENST00000264668; = p.R585S on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV52945613; called by muse, mutect2, varscan2
- NELFA | c.1445G>T p.C482F (on ENST00000542778; = p.C471F on NM_005663.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56393888; called by muse, mutect2, varscan2
- NPC1 | c.3428G>A p.W1143* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as CM012443, COSV99340164; called by muse, mutect2
- OR2AG2 | c.810A>C p.Q270H | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58455772; called by muse, mutect2, varscan2
- OR3A1 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV60163576; called by muse, mutect2, varscan2
- P3H1 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 338/510 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV52534033; called by muse, mutect2, varscan2
- PAPPA | c.3044C>G p.T1015R | Missense Mutation (SNP) | VAF 248/630 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60288614; called by muse, mutect2, varscan2
- PCDH17 | c.2510C>A p.T837N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV64976886; called by muse, mutect2, varscan2
- PGAM4 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.197); catalogued as COSV58446842; called by muse, mutect2
- PKN3 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV99403663; called by muse, mutect2
- PM20D1 | c.428G>C p.G143A | Missense Mutation (SNP) | VAF 106/650 reads (16%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.94); catalogued as COSV65649358; called by muse, mutect2, varscan2
- RELN | c.473+1G>T p.X158_splice | Splice Site (SNP) | VAF 16/436 reads (4%) | catalogued as COSV100633884, COSV58983802; called by muse, mutect2
- RNPS1 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.874); catalogued as COSV57044427; called by mutect2, varscan2
- S1PR3 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV63980993; called by muse, mutect2, varscan2
- SALL1 | c.2705C>T p.S902L | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV99174196; called by muse, mutect2
- SCARF1 | c.1385C>A p.T462N | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV99557076; called by muse, mutect2
- SCN10A | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 44/346 reads (13%) | catalogued as rs1168396269, COSV71860734; called by muse, mutect2, varscan2
- SEMA5B | c.3427C>T p.P1143S | Missense Mutation (SNP) | VAF 110/687 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as COSV99531981; called by muse, mutect2, varscan2
- SH3PXD2B | c.2173T>G p.S725A | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV61128562; called by muse, mutect2, varscan2
- SIDT2 | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773432083, COSV54059012; called by muse, mutect2, varscan2
- SLC30A3 | c.613dup p.H205Pfs*6 | Frame Shift Ins (INS) | VAF 11/66 reads (17%) | catalogued as rs745429257; called by mutect2, varscan2
- SLF1 | c.3164T>C p.M1055T | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1191587008, COSV54372066; called by muse, mutect2, varscan2
- SNRNP200 | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 53/285 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs780925650, COSV60492463, COSV60493574; called by muse, mutect2, varscan2
- SPOUT1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63509675; called by muse, mutect2, varscan2
- SRRM4 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); catalogued as rs753604308, COSV57415682; called by muse, mutect2
- TAB2 | c.323G>C p.S108T | Missense Mutation (SNP) | VAF 20/437 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99644839; called by muse, mutect2
- TLR4 | c.845A>G p.N282S (on ENST00000355622 / NM_138554.5; = p.N242S on NM_003266.4) | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV62923859; called by muse, mutect2, varscan2
- TP53 | c.863dup p.N288Kfs*18 | Frame Shift Ins (INS) | VAF 175/262 reads (67%) | catalogued as COSV99387464; called by mutect2, varscan2
- UGT2B17 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV58502227; called by muse, mutect2, varscan2
- UQCRB | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 46/1000 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV99749177; called by muse, mutect2
- WDR1 | c.1069G>A p.D357N (on ENST00000382452; = p.D217N on NM_005112.5) | Missense Mutation (SNP) | VAF 44/478 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs948439276, COSV101221119; called by muse, mutect2
- WDR36 | c.1756A>G p.M586V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1350321527, COSV72605378; called by muse, mutect2, varscan2
- ZFP36 | c.859C>T p.P287S (on ENST00000594442; = p.P281S on NM_003407.5) | Missense Mutation (SNP) | VAF 283/347 reads (82%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.961); catalogued as rs1030508872, COSV99953842, COSV99953965; called by muse, varscan2
- ZHX1 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 21/385 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52878727, COSV99933704; called by muse, mutect2
- ZNF721 | c.1582C>T p.Q528* (on ENST00000338977; = p.Q540* on NM_133474.4) | Nonsense Mutation (SNP) | VAF 42/135 reads (31%) | catalogued as rs1553863486, COSV59095249; called by muse, mutect2, varscan2
- ARHGEF3 | c.597_598del p.I200Pfs*12 | Frame Shift Del (DEL) | VAF 26/123 reads (21%) | called by pindel, varscan2
- BSN | c.8702del p.P2901Lfs*27 | Frame Shift Del (DEL) | VAF 18/120 reads (15%) | called by mutect2, pindel, varscan2
- CATSPERD | c.2334_2335insGAGGGACTCCGACTCAAAAAA p.A778_R779insEGLRLKK | In Frame Ins (INS) | VAF 126/179 reads (70%) | called by mutect2, varscan2*
- CCDC32 | c.441dup p.V148Sfs*19 | Frame Shift Ins (INS) | VAF 59/268 reads (22%) | called by mutect2, pindel, varscan2
- CDH12 | c.186dup p.V63Cfs*43 | Frame Shift Ins (INS) | VAF 48/207 reads (23%) | called by mutect2, pindel, varscan2
- LILRB1 | c.1798C>G p.R600G (on ENST00000427581; = p.R550G on NM_006669.6) | Missense Mutation (SNP) | VAF 72/367 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.392); called by muse, mutect2
- OR10H4 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 48/983 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2
- PRSS16 | c.883_884del p.V295Sfs*4 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by pindel, varscan2
- SCG5 | c.500T>C p.L167P (on ENST00000300175 / NM_001144757.2; = p.L166P on NM_003020.4) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); called by mutect2, varscan2
- SYT2 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); called by muse, mutect2
- TRAPPC4 | c.218_222del p.G73Vfs*14 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by mutect2, varscan2
- AGAP2 | c.1791C>A p.G597= (on ENST00000547588 / NM_001122772.2; = p.G261= on NM_014770.4) | Silent (SNP) | VAF 5/46 reads (11%) | called by mutect2, varscan2
- AMACR | c.1032T>C p.P344= | Silent (SNP) | VAF 37/199 reads (19%) | called by mutect2, varscan2
- CCDC83 | c.1095G>A p.L365= (on ENST00000342404 / NM_001286159.2; = p.L396= on NM_173556.5) | Silent (SNP) | VAF 36/562 reads (6%) | catalogued as COSV99721724; called by muse, mutect2
- CSMD2 | c.9585G>A p.T3195= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs763272968, COSV53901175; called by muse, mutect2, varscan2
- ERBB2 | c.2373A>C p.T791= | Silent (SNP) | VAF 76/324 reads (23%) | called by mutect2, varscan2
- F5 | c.975C>T p.D325= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV100889123; called by muse, mutect2, varscan2
- FCAR | c.714C>T p.L238= | Silent (SNP) | VAF 311/2283 reads (14%) | catalogued as rs944126574, COSV62029084; called by muse, mutect2, varscan2
- FCRL5 | c.2361T>C p.F787= | Silent (SNP) | VAF 23/185 reads (12%) | catalogued as COSV62517754; called by muse, mutect2, varscan2
- FEZF1 | c.933G>A p.T311= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV58659288; called by muse, mutect2, varscan2
- GDF6 | c.219C>T p.D73= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as rs753416812, COSV54626113; called by muse, mutect2, varscan2
- HSD17B7 | c.735G>A p.P245= | Silent (SNP) | VAF 29/190 reads (15%) | catalogued as rs753284660, COSV54419241; called by muse, mutect2, varscan2
- IGFN1 | c.2628C>A p.A876= (on ENST00000295591 / NM_001367841.1; = p.A3333= on NM_001164586.2) | Silent (SNP) | VAF 14/303 reads (5%) | catalogued as COSV99812508; called by muse, mutect2
- JPH2 | c.1275C>T p.D425= | Silent (SNP) | VAF 26/348 reads (7%) | catalogued as COSV100881741; called by muse, mutect2
- KCNG3 | c.885G>A p.R295= | Silent (SNP) | VAF 9/131 reads (7%) | catalogued as COSV100045095; called by muse, mutect2
- KLHL1 | c.171C>T p.L57= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs773746540, COSV64766964, COSV64777483; called by muse, mutect2, varscan2
- LYZL1 | c.381G>T p.A127= (on ENST00000375500; = p.A81= on NM_032517.6) | Silent (SNP) | VAF 28/412 reads (7%) | catalogued as COSV100973641; called by muse, mutect2
- METTL16 | c.1326C>T p.A442= | Silent (SNP) | VAF 33/157 reads (21%) | catalogued as rs761726784, COSV54015244; called by muse, mutect2, varscan2
- MTF1 | c.534C>T p.G178= | Silent (SNP) | VAF 41/345 reads (12%) | catalogued as COSV65989986; called by muse, mutect2, varscan2
- NOMO1 | c.1158T>C p.F386= | Silent (SNP) | VAF 10/426 reads (2%) | catalogued as COSV99814564; called by muse, mutect2
- NUP160 | c.159C>T p.R53= | Silent (SNP) | VAF 62/158 reads (39%) | catalogued as COSV65855224; called by muse, mutect2, varscan2
- OR51S1 | c.390G>C p.R130= | Silent (SNP) | VAF 105/298 reads (35%) | catalogued as COSV59059312; called by muse, mutect2, varscan2
- OR5D14 | c.402T>C p.Y134= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV59457564; called by muse, mutect2, varscan2
- SALL1 | c.2691C>T p.V897= | Silent (SNP) | VAF 42/264 reads (16%) | catalogued as rs750151915, COSV99174200; called by muse, mutect2
- SEMA4A | c.267C>T p.I89= | Silent (SNP) | VAF 10/334 reads (3%) | catalogued as COSV100740605; called by muse, mutect2
- SLIT3 | c.2976G>T p.R992= | Silent (SNP) | VAF 16/422 reads (4%) | catalogued as COSV100267949; called by muse, mutect2
- TAS2R14 | c.120G>A p.K40= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV67863148; called by muse, mutect2
- TDRD1 | c.438C>T p.V146= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as rs1462023200, COSV52593413; called by muse, mutect2, varscan2
- TIAM1 | c.63G>T p.L21= | Silent (SNP) | VAF 89/725 reads (12%) | catalogued as COSV99735473; called by muse, mutect2, varscan2
- TUBA3E | c.714C>A p.I238= | Silent (SNP) | VAF 22/274 reads (8%) | catalogued as COSV99919836; called by muse, mutect2
- ZBTB17 | c.321C>G p.A107= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs1194201488, COSV65270918; called by muse, mutect2, varscan2
- BTN2A3P | n.135C>G | RNA (SNP) | VAF 56/456 reads (12%) | called by mutect2, varscan2
- MGLL | c.233-13151C>T | Intron (SNP) | VAF 326/768 reads (42%) | catalogued as COSV54023031; called by muse, varscan2
- MGLL | c.233-13204C>T | Intron (SNP) | VAF 348/694 reads (50%) | catalogued as COSV99411920; called by muse, varscan2
- WT1 | chr11:32439077 G>A | 5'Flank (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
